Surgical pathology report (de-identified scan), TCGA case TCGA-29-1691, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1691-01A (Primary Tumor).

[page 1 of 3]
Surg Path

TCGA-29-1691

CLINICAL HISTORY:

Ovarian cancer.

Additional history: Left ovary, history of bilateral breast cancer in the
? mets. ? ovarian cancer.

GROSS EXAMINATION:

A. "Left ovary", in formalin. Received is a large brown and tan mass which measures 12.5 x 9 x 7 cm. The surface has a diffuse, finely papillary growth with numerous larger nodules. On cut sections, the majority of the tumor is solid but has a variegated appearance with areas which are white and yellow and other areas which appear hemorrhagic. The papillary growth is present diffusely throughout.

Block Summary:

A1 - Frozen section remnant AF1.

A2-A4 Tumor.

B. "Umbilical hernia sac", in formalin. Received is a portion of fibroadipose tissue which measures 5.5 x 4 x 2 cm. It contains a firm white and tan finely nodular area which measures 3 x 1.7 x 0.5 cm consistent with tumor. Representative sections are submitted in Block B1.

C. "Small bowel nodule", in formalin. Several pieces of tan-white tissue with a finely papillary surface consistent with tumor. Representative sections submitted in Block C1. The specimen measures in toto 3.5 x 2 x 1 cm.

D. "Right diaphragm", in formalin. A white papillary nodule which measures 1.5 x 0.6 x 0.6 cm. Submitted in toto in Block D1.

E. "Omentum", in formalin. A large portion of fibroadipose tissue consistent with omentum which measures 26 x 20 x 4 cm. The specimen is serially sectioned revealing numerous firm white nodules and cystic areas. Representative sections are submitted in Block E1.

F. "Right ovary", in formalin. Received are several fragments of hemorrhagic and white solid tumor with a finely papillary surface. The specimen measures in aggregate 15 x 14 x 5.5 cm. There are also several clear cysts which express clear yellow fluid. On cut section, the tumor is mainly solid with many areas of hemorrhage and necrosis. No clear residual ovary is identified. Representative sections are submitted in [REDACTED]

G. "Bladder flap", in formalin. Several pieces of fibroadipose tissue containing a solid white papillary lesion. The specimen measures in aggregate 6.4 x 3.4 x 2.5 cm. Representative sections are submitted in Block G1.

H. "Anterior cul-de-sac", in formalin. A portion of fibroadipose tissue with a papillary white nodular growth. The specimen measures 4.5 x 2 x 0.5 cm and representative sections are submitted in Block H1.

I. "Posterior cul-de-sac", in formalin. Several pieces of firm, white tissue with a finely nodular papillary surface which measures in aggregate 7.5 x 5.5 x 4.5 cm. Representative sections are submitted in Block I1.

J. "Sigmoid colon", in formalin. Received are several portions of fibroadipose tissue containing firm, white nodules. The specimen measures in aggregate 10 x 7 x 4 cm. Representative sections submitted in Block J1.

K. "Right sidewall", in formalin. Several portions of fibroadipose tissue

[page 2 of 3]
which measure in aggregate 2 x 1 x 1.5 cm. A representative section is submitted in Block K1. A firm white nodule is present.

L. "Right gutter", in formalin. A portion of fibroadipose tissue which measures 9.5 x 4.5 x 0.7 cm which contains several firm, white nodules. Representative sections are submitted in Block L1.

M. "Ventral hernia sac", in formalin. A portion of fibroadipose tissue which measures 4.2 x 2.5 x 1.5 cm. The specimen is sectioned revealing white fibrous tissue, but no tumor nodules are identified. Representative sections are submitted in Block M1.

N. "Anterior abdominal peritoneal wall", in formalin. A portion of fibroadipose tissue which measures 9 x 4.8 x 0.7 cm. There is a firm white nodule which measures 2 x 0.9 x 0.4 cm and a second attached piece which contains papillary white nodular growths. Representative sections are submitted in Block N1.

TCGA-29-1691

INTRA OPERATIVE CONSULTATION:

AF1 - "Left ovary": Adenocarcinoma with some papillary differentiation - favor ovarian primary

DIAGNOSIS:

LEFT (A) & RIGHT (F) OVARIES (A): SEROUS ADENOCARCINOMA, FIGO GRADE 2, WITH METASTASES TO:

- B. UMBILICAL HERNIA SAC.
- C. SMALL BOWEL NODULE.
- D. RIGHT DIAPHRAGM.
- E. OMENTUM.
- F. RIGHT OVARY.
- G. BLADDER FLAP.
- H. ANTERIOR CUL-DE-SAC.
- I. POSTERIOR CUL-DE-SAC.
- J. SIGMOID COLON.
- K. RIGHT SIDE WALL.
- L. RIGHT GUTTER.
- N. ANTERIOR ABDOMINAL PERITONEAL WALL.

THE FOLLOWING SPECIMEN IS FREE OF TUMOR:
M. VENTRAL HERNIA SAC.

NOTE: While many areas in the tumor are solid (estimated 30%), the tumor is classified as grade 2 since less than 50% is solid.

Verified by:

ADDENDUM 1:

This addendum is issued to report the results for immunostaining for HER2/neu oncoprotein. The test is performed at the request of

Immunostaining for HER2/neu (c-erbB-2) oncoprotein is performed on recut sections of block A2 ("left ovary"). The immunostaining is done using DAKO rabbit anti-human c-erbB-2 oncoprotein which is an affinity-isolated antibody (DAKO product number A0485). The immunostaining is performed after antigen retrieval by heating the unstained sections at 95 degrees centigrade for 20 minutes in 10 mM citrate buffer, pH 6.0. The primary antibody is used at a dilution of 1:1500 (manual staining) or 1:2000 (autostainer), with an incubation for one hour at 37 degrees centigrade. The Histostain Plus kit (Zymed Laboratories) is used as the detection system. The histological section consists predominantly of serous adenocarcinoma with areas of papillary differentiation. The tumor has a variable immunostaining profile. The majority of the tumor has negligible staining of the cytoplasm or cell membrane (score = 0). There is a minority population of the tumor cells that

[page 3 of 3]
has trace staining of the cytoplasm with mildly to moderately intense circumferential staining of the cell membrane. These cells with circumferential cell membrane staining are present as multiple foci scattered throughout the tumor. This makes it difficult to estimate the overall tumor population with the staining pattern indicative of weak overexpression of HER2/neu oncoprotein, but I estimate that such cells account for approximately 5% of the tumor cells.

In summary, the serous adenocarcinoma present in the left ovary has a subpopulation of tumor cells (approximately 5% of the total population) with an immunostaining profile indicative of mild overexpression of HER2/neu oncoprotein.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED] TCGA-29-1691

[REDACTED]

Source: NCI Genomic Data Commons file a60aa72e-44c5-4131-9626-f126a10103ee (TCGA-29-1691.74E45220-B3AC-4404-8BB6-811F3D4BA611.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).